MMRF case MMRF_2440 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/7454fcff-7db7-4a0a-be8a-d12fa315c0e9

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 47 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 47.1 years (17,208 days); ISS stage: II; Days to last known disease status: 722 days (2.0 years); Days to last follow up: 722 days (2.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 84 days.
   Treatment given: Therapeutic agents: Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 88 days; Days to treatment end: 88 days.
   Treatment given: Therapeutic agents: Melphalan; Regimen or line of therapy: First line of therapy; Days to treatment start: 113 days; Days to treatment end: 113 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 115 days; Days to treatment end: 115 days.
   Treatment given: Therapeutic agents: Bortezomib + Dexamethasone + Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 210 days; Days to treatment end: 253 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 259 days; Days to treatment end: 349 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 350 days; Days to treatment end: 462 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 463 days (1.3 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -7 (ECOG 1): M Protein 4.83 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 141 mg/dL; Immunoglobulin G 65.3 g/L; Immunoglobulin A 0.39 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 3.8 µg/mL; Lactate Dehydrogenase 2.63 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 4 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 7.5 mmol/L; Calcium 2.35 mmol/L; Albumin 36 g/L; Total Protein 11.5 g/dL; Glucose 4.79 mmol/L; C-Reactive Protein 0.014 mg/dL.
- Day 85 (ECOG 0): M Protein 0.16 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.85 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.92 mg/dL; Immunoglobulin G 6.51 g/L; Immunoglobulin A 0.21 g/L; Immunoglobulin M 0.19 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 238 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.1 mmol/L; Albumin 41 g/L; Total Protein 6.5 g/dL; Glucose 5.83 mmol/L.
- Day 169 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.67 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.65 mg/dL; Immunoglobulin G 5.9 g/L; Immunoglobulin A 0.3 g/L; Immunoglobulin M 0.16 g/L; Beta 2 Microglobulin 2.1 µg/mL; Hemoglobin 8.74 mmol/L; Leukocytes 7.4 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 176 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.4 mmol/L; Albumin 44 g/L; Total Protein 7.2 g/dL; Glucose 6.33 mmol/L.
- Day 247 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.68 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.35 mg/dL; Immunoglobulin G 5.44 g/L; Immunoglobulin A 0.29 g/L; Immunoglobulin M 1.69 g/L; Beta 2 Microglobulin 1.6 µg/mL; Hemoglobin 8.87 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 99 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.13 mmol/L; Albumin 40 g/L; Total Protein 6.9 g/dL; Glucose 5.39 mmol/L.
- Day 350 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.03 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.26 mg/dL; Immunoglobulin G 8.47 g/L; Immunoglobulin A 0.18 g/L; Immunoglobulin M 0.14 g/L; Beta 2 Microglobulin 2.47 µg/mL; Hemoglobin 8.87 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 149 ×10⁹/L; Creatinine 79.6 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.2 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.79 mmol/L.
- Day 435 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.44 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.31 mg/dL; Immunoglobulin G 9.14 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.1 g/L; Beta 2 Microglobulin 1.64 µg/mL; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 7.63 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.23 mmol/L; Albumin 41 g/L; Total Protein 6.7 g/dL; Glucose 5.45 mmol/L.
- Day 526 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.53 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.77 mg/dL; Immunoglobulin G 10.3 g/L; Immunoglobulin A 0.25 g/L; Immunoglobulin M 0.12 g/L; Beta 2 Microglobulin 1.54 µg/mL; Lactate Dehydrogenase 1.97 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 2.7 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 117 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.3 mmol/L; Albumin 42 g/L; Total Protein 6.9 g/dL; Glucose 5.39 mmol/L.
- Day 610 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.42 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.87 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 0.26 g/L; Immunoglobulin M 0.11 g/L; Beta 2 Microglobulin 1.92 µg/mL; Lactate Dehydrogenase 1.75 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 2.4 ×10⁹/L; Absolute Neutrophil 1.2 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 97.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.18 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 4.79 mmol/L.
- Day 722 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.49 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2 mg/dL; Immunoglobulin G 11.4 g/L; Immunoglobulin A 0.27 g/L; Immunoglobulin M 0.09 g/L; Beta 2 Microglobulin 1.95 µg/mL; Lactate Dehydrogenase 1.85 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 2.2 ×10⁹/L; Absolute Neutrophil 0.9 ×10⁹/L; Platelets 119 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 43 g/L; Total Protein 7 g/dL; Glucose 6.05 mmol/L.

Other clinical attributes
- Day -7: Weight: 86 kg; Height: 185 cm.

Family history
- Relative with cancer history: yes; Relationship type: Mother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.

Biospecimens (2 samples)
- Sample MMRF_2440_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -7 days.
- Sample MMRF_2440_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -7 days.
